Gene-level copy-number profile of tumor specimen TARGET-10-PATLHS-09A from TARGET case TARGET-10-PATLHS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.0 years (4,004 days).
Specimen TARGET-10-PATLHS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.a252628b-e838-57da-b975-1f739d6303ae.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATLHS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 370 have no estimate.
https://portal.gdc.cancer.gov/files/ed57228e-aea9-468c-8078-0bd7d46ef1af

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 139; copy number 1: 2,408; copy number 2: 1,311; copy number 3: 657; copy number 4: 55,450; copy number 5: 25; copy number 6: 12; copy number 7: 169; copy number 8: 82.

Homozygous deletions (total copy number 0; autosomes only): 139 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–147,003,618, 111 genes (broad region; genes not listed).
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes: TRGV5P, TRGV5, TRGV4.
- chr9:21,929,457–22,214,672, 10 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 44. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
